Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8A9, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8A9-01A (Primary Tumor).

[page 1 of 2]
Panel: Surgical Pathology Final Report

Date:

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-in progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
Surgical Pathology Final Report						
Collection d/t:						

Obs d/t:

Ordered by:

Surgical Pathology Report

ICD-03

Seminoma NOS 9061/3

Site: (R) Testis NOS C62.9

7/25/2014

Final Diagnosis

1. Testis, right, orchiectomy:
- A. Seminoma, classic type, 2.4cm, with involvement of rete testis, see note. Lymphovascular invasion is present. No invasion into tunica vaginalis or epididymis is seen.
- B. Intratubular germ cell neoplasia.
- C. Spermatic cord margin free of tumor.
- D. Focal Leydig cell hyperplasia.
- E. 1.6 cm benign epididymal cyst.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Note

Selected slides reviewed at

Pathologist(s)

Gross Description

The case is received in one container, labeled with the patient's name and medical record number.

Specimen 1 is received fresh designated "right testicle" and consists of a orchiectomy specimen measuring overall 14.2 x 5.1 x 2.4 cm, with a

[page 2 of 2]
spermatic cord measuring 8.3 cm in length and 1.6 cm in diameter, and a testis measuring 6.2 cm x 4.9 x 2.4 cm. The specimen weighs 40.2 g. The surface of the testicle is smooth and intact. The external surface of the specimen is inked black. The spermatic cord margin is shaved and submitted in 1A. Testis is bisected to reveal a firm, white-tan mass that measures 2.4 x 2.0 x 1.9 cm. The mass does not grossly involve the epididymis or the rete testis. There is also a cystic structure which measures 1.6 cm in greatest dimension which is located at the inferior aspect of the testis. The cyst wall lining is smooth and the cyst is filled with clear fluid. The spermatic cord is sectioned and is grossly unremarkable. Representative section are submitted as follows:

1B is a section of the midportion of the spermatic cord.

1C is a section of the base of the right cord.

The tumor is submitted in toto in sections 1B through 1L.

Representative sections of grossly uninvolved testis and the cystic lesion are submitted in 1M and 1N.

SUMMARY OF SECTIONS: 14, cms, representative

Dictated by:

Clinical Information

year-old male with right testicular mass

Pre-Operative Diagnosis: Not specified

Post-Operative Diagnosis: Not specified

Operation: Orchiectomy, right, inguinal approach

Specific questions to be answered: No questions.

Specimen:

1. Testis, Tumor, Right

*** End of report ***

Source: NCI Genomic Data Commons file 9fa30571-d056-4a0b-8a69-36ffd5f1061d (TCGA-VF-A8A9.28768044-28A3-44EB-B6C7-5B9735D0535E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).